Somatic mutation profile of tumor specimen TCGA-WT-AB41-01A (aliquot TCGA-WT-AB41-01A-11D-A41F-09) from TCGA case TCGA-WT-AB41, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB.
Specimen TCGA-WT-AB41-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 933bc478-9a3a-4909-80ae-7326910cdcfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WT-AB41-10A (Blood Derived Normal), aliquot TCGA-WT-AB41-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a7dcf94-b3d7-4516-9736-db8fdb7b451a

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 8, Splice Site 1, Nonsense Mutation 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EHMT1 | c.3127C>T p.Q1043* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as rs1064796996, COSV101509667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7989dup p.K2664* (on ENST00000358273 / NM_001042492.3; = p.K2643* on NM_000267.3) | Frame Shift Ins (INS) | VAF 13/55 reads (24%) | catalogued as rs1555536882, CI001029; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 33/91 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2620C>G p.H874D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221292; called by muse, mutect2, varscan2
- AATK | c.826C>T p.H276Y (on ENST00000326724 / NM_001080395.3; = p.H173Y on NM_004920.2) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100452798; called by muse, mutect2, varscan2
- ADAMTS13 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as COSV100747086; called by muse, mutect2
- AGL | c.2930G>T p.R977L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.298); catalogued as rs147977213, COSV54051490; called by muse, mutect2
- ANKRD20A2P | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 29/452 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0.301); catalogued as COSV66464271; called by muse, mutect2
- ARHGAP33 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs61762677, COSV50252621; called by muse, mutect2, varscan2
- ARID1A | c.2879-1G>A p.X960_splice | Splice Site (SNP) | VAF 14/33 reads (42%) | catalogued as COSV61372173, COSV61380279; called by muse, mutect2, varscan2
- ATP2B3 | c.1749G>A p.M583I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99684448; called by muse, mutect2, varscan2
- CHIA | c.1418G>A p.C473Y (on ENST00000343320; = p.C365Y on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100588673; called by muse, mutect2, varscan2
- CWF19L1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100821522; called by muse, mutect2, varscan2
- DCDC1 | c.3529C>T p.H1177Y (on ENST00000597505 / NM_001367979.1; = p.H284Y on NM_020869.3) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100338281; called by muse, mutect2, varscan2
- DISP1 | c.3160G>A p.V1054I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); catalogued as rs766641928, COSV52655362; called by muse, mutect2
- DOCK10 | c.1847G>A p.S616N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51411870; called by muse, mutect2, varscan2
- EME1 | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as COSV99868920; called by muse, mutect2, varscan2
- HELZ | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100698723; called by muse, mutect2, varscan2
- IGHV1-18 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as rs782433966; called by muse, mutect2
- ITCH | c.2605C>T p.H869Y (on ENST00000262650 / NM_001257137.3; = p.H828Y on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99392488; called by muse, mutect2, varscan2
- KIAA1217 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs769759620, COSV100907969; called by muse, mutect2, varscan2
- MBIP | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.922); catalogued as COSV100576782; called by muse, mutect2, varscan2
- METTL26 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284495769, COSV100037384; called by muse, mutect2, varscan2
- NEDD4L | c.2524A>G p.I842V (on ENST00000400345 / NM_001144967.3; = p.I822V on NM_015277.6) | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV56848078, COSV99894868; called by muse, mutect2, varscan2
- PEAR1 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs779757993, COSV99441461; called by muse, mutect2, varscan2
- PMCH | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100268233; called by muse, mutect2, varscan2
- PTGER2 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as rs749812686, COSV55419165, COSV55419729; called by muse, mutect2, varscan2
- SPTBN2 | c.6640G>A p.E2214K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.146); catalogued as COSV100019375; called by muse, mutect2, varscan2
- SPTY2D1 | c.1561G>T p.G521W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100311678; called by muse, mutect2, varscan2
- SPTY2D1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.15); catalogued as COSV100311435, COSV100311684; called by muse, mutect2, varscan2
- TERT | c.3103G>A p.V1035I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs374968697; called by muse, mutect2, varscan2
- TMCO6 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.154); catalogued as COSV99347168; called by muse, mutect2, varscan2
- TNNT1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52573424; called by muse, mutect2
- TREM1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs748711105, COSV55149353; called by muse, mutect2, varscan2
- ZNF184 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99279660; called by muse, mutect2, varscan2
- ADA2 | c.1365C>T p.F455= (on ENST00000262607; = p.F214= on NM_177405.3) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV52830751, COSV52833578; called by muse, mutect2
- COPB1 | c.1425G>A p.V475= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99999585; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2211G>T p.G737= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100668611, COSV62570661; called by muse, mutect2, varscan2
- EPHA1 | c.2460G>T p.L820= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV99314004; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.114T>G p.L38= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99880568; called by muse, mutect2, varscan2
- FOXJ3 | c.1575G>A p.Q525= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs757960670, COSV100691803; called by muse, mutect2, varscan2
- SPACA3 | c.306C>T p.F102= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs775934021, COSV52191672; called by muse, mutect2, varscan2
- TRMT9B | c.51C>T p.Y17= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs764131417, COSV67948524; called by muse, mutect2, varscan2
- GABRB3 | chr15:26773663 C>T | 5'Flank (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100159990, COSV54681889; called by muse, mutect2
